Surgical pathology report (de-identified scan), TCGA case TCGA-WY-A858, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Johns Hopkins, specimen TCGA-WY-A858-01A (Primary Tumor).

[page 1 of 5]
Patient: [REDACTED]

Path# [REDACTED]

[REDACTED] # [REDACTED]

Accessioned

Birthdate: [REDACTED]

(Age

Loc: [REDACTED]

Gender: F

Spec. Taken

=====

INTERPRETATION AND DIAGNOSIS:

1-5) BRAIN TUMOR: ANAPLASTIC ASTROCYTOMA, WHO GRADE III, SEE COMMENT.

COMMENT: While some of the lesion is grade II, tissue in 1A has the cellularity, nuclear atypia, and mitotic activity of a grade III lesion. The MIB-1 rate is approximately 5%. While there are some oligodendroglioma features, i.e. round uniform nuclei and perivascular haloes, the tumor, overall, has features of astrocytoma. Molecular studies found changes consistent with loss of heterozygosity on 19q, but not on 1p. As such, the 1p/19q codeletion associated with oligodendroglioma was not present. Isolated loss of 19q is not uncommon in astrocytomas.

[REDACTED]

*Electronic signature

Some stains/tests used in arriving at the diagnosis were performed here using reagents that have not been cleared or approved by the US Food and Drug Administration. These were developed and their performance determined by the [REDACTED] Their use does not require FDA approval.

=====

Clinical History:
BRAIN TUMOR

GROSS DESCRIPTION

(Continued on next page.)

ICD-O-3
Astrocytoma, grade III 9401/3
Site: 4 Brain, supratentorial NOS C71.1
4 Brain NOS C71.9
4/26/10/14

[page 2 of 5]
[REDACTED] Patient: [REDACTED]

Path# [REDACTED]

[REDACTED] # [REDACTED]

Page 2

=====

PART #1: FS: BRAIN TUMOR

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists / [REDACTED]

FS: Brain tumor: Infiltrating glioma.

Dictated by: [REDACTED]

The specimen is received in saline for frozen section labeled with the patient's name, [REDACTED] and is designated 'brain tumor'. The specimen consists of multiple pieces and fragments of white, pale tan-red, mucoid soft tissue measuring 2.1 x 0.9 x 0.4 cm in aggregate. 50% of the specimen is used for frozen section. The specimen is submitted in its entirety in lens paper.

SUMMARY OF SECTIONS

1 - FSC - MULTIPLE
1 - A - MULTIPLE
2 - TOTAL - M

(Continued on next page.)

[page 3 of 5]
[REDACTED] Patient: [REDACTED]

Path# [REDACTED]

[REDACTED] # [REDACTED]

Page 3

=====

PART #2: FS: BRAIN TUMOR

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists / PAs: [REDACTED]

FS: Brain tumor: Infiltrating glioma.

Dictated by: [REDACTED]

The specimen is received in saline for frozen section labeled with the patient's name, [REDACTED] and is designated 'brain tumor'. The specimen consists of multiple pieces and fragments of tan-red, mucoid soft tissue measuring 2.2 x 1.0 x 0.6 cm in aggregate. Approximately 50% of the specimen is used for frozen section. The specimen is submitted in its entirety in lens paper.

SUMMARY OF SECTIONS

1 - FSC - MULTIPLE
1 - A - MULTIPLE
2 - TOTAL - M

(Continued on next page.)

[page 4 of 5]
Patient: [REDACTED]

Path# [REDACTED]

[REDACTED] # [REDACTED]

Page 4

=====

PART #3: FS: CYST WALL

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists / [REDACTED]

FS: Cyst wall: Infiltrating glioma.

Dictated by: [REDACTED]

The specimen is received in saline for frozen section labeled with the patient's name, [REDACTED] and is designated 'cyst wall'. The specimen consists of multiple pieces and fragments of tan-red, mucoid and fibrous soft tissue measuring 2.0 x 1.0 x 0.4 cm in aggregate. Approximately 50% of the specimen is used for frozen section. The specimen is submitted in its entirety in lens paper.

SUMMARY OF SECTIONS

1 - FSC - MULTIPLE
1 - A - MULTIPLE
2 - TOTAL - M

(Continued on next page.)

[page 5 of 5]
Patient: [REDACTED]

Path# [REDACTED]

[REDACTED] # [REDACTED]

Page 5

PART #4: ANTERIOR FRONTAL LOBE

Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

The specimen is received in saline labeled with the patient's name, [REDACTED] and is designated 'anterior frontal lobe'. The specimen consists of one large mass and multiple fragments of white-yellow-tan-red, mucoid and fibrous soft tissue measuring 2.5 x 2.0 x 1.1 cm in aggregate. The largest mass is trisected. The specimen is submitted in its entirety in lens paper.

SUMMARY OF SECTIONS

1 - A - MULTIPLE
1 - B - 1
1 - C - 1
3 - TOTAL - M

PART #5: TUMOR

Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

The specimen is received in saline labeled with the patient's name, [REDACTED] and is designated 'tumor'. The specimen consists of multiple pieces and fragments of white, pale tan-red, mucoid and fibrous soft tissue measuring 4.0 x 2.5 x 1.0 cm in aggregate. The specimen is submitted in its entirety in lens paper.

SUMMARY OF SECTIONS

3 - A-C - MULTIPLE
3 - TOTAL - M

(End of Report)

printed

Reviewer Initials: [REDACTED] Date Reviewed: 10/25/13		

Source: NCI Genomic Data Commons file db140862-e705-44d7-b5ad-0162847915fd (TCGA-WY-A858.1CC7D858-5937-4D9D-8C7A-355F24D49219.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).